Somatic mutation profile of tumor specimen TCGA-A4-A5XZ-01A (aliquot TCGA-A4-A5XZ-01A-11D-A31X-10) from TCGA case TCGA-A4-A5XZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 65.7 years (24,006 days).
Specimen TCGA-A4-A5XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 561d61f4-c6af-477c-93c3-eeb1b42e2674.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A5XZ-10A (Blood Derived Normal), aliquot TCGA-A4-A5XZ-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3390434e-524d-45c9-bbda-228965a2d737

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 38, Silent 12, Frame Shift Ins 3, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2377A>G p.K793E | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV55942033; called by muse, mutect2, varscan2
- ADAM20 | c.1858T>G p.C620G | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56456710; called by muse, mutect2, varscan2
- ALDH1L1 | c.2356T>G p.F786V | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.613); catalogued as COSV56419554; called by muse, mutect2, varscan2
- ARHGAP22 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV50989578; called by muse, mutect2, varscan2
- ATRAID | c.364A>G p.N122D (on ENST00000611786; = p.N9D on NM_016085.5) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.318); catalogued as COSV53032158; called by muse, mutect2, varscan2
- BCL2L10 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV53064928; called by muse, mutect2, varscan2
- CADM2 | c.139G>C p.D47H (on ENST00000407528 / NM_001167674.2; = p.D49H on NM_153184.4) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV67405529; called by muse, mutect2
- CDKAL1 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV51192568; called by mutect2, varscan2
- CEACAM16 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754040589, COSV69188458, COSV69188693; called by muse, mutect2, varscan2
- COL9A3 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs1440423945, COSV58987314; called by muse, mutect2, varscan2
- DDN | c.1844T>A p.V615E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV70405279; called by muse, mutect2, varscan2
- DDX5 | c.1256C>G p.P419R | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56751435; called by muse, mutect2, varscan2
- DNA2 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV64430304; called by muse, mutect2, varscan2
- EXD2 | c.636G>C p.E212D (on ENST00000312994 / NM_001193362.1; = p.E87D on NM_018199.3) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV57282302; called by muse, mutect2, varscan2
- HTT | c.8107T>C p.S2703P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV61869738; called by muse, mutect2, varscan2
- IK | c.555A>C p.E185D | Missense Mutation (SNP) | VAF 147/444 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as COSV70258256; called by muse, mutect2, varscan2
- LRRC8C | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs113075842, COSV65001570; called by muse, mutect2, varscan2
- LYZ | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV54261388; called by muse, mutect2, varscan2
- MIDEAS | c.52T>A p.F18I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV54099257; called by muse, mutect2, varscan2
- NFYA | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58200003; called by muse, mutect2, varscan2
- OGDH | c.2849dup p.N950Kfs*3 | Frame Shift Ins (INS) | VAF 31/97 reads (32%) | catalogued as COSV56045471; called by mutect2, pindel, varscan2
- PASK | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52160899; called by muse, mutect2, varscan2
- PCDHA12 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.253); catalogued as COSV56487703; called by muse, mutect2
- POLRMT | c.1216A>G p.M406V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1213660824, COSV73933682; called by muse, mutect2, varscan2
- PRKDC | c.3505G>C p.V1169L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58048842, COSV58064381; called by muse, mutect2, varscan2
- RPL19 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV56636502; called by muse, mutect2, varscan2
- SCFD1 | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV61727556; called by muse, mutect2, varscan2
- SMG8 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as COSV99958614; called by muse, mutect2
- SNAP47 | c.293T>A p.I98K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59920291; called by muse, mutect2, varscan2
- SPEG | c.4798T>C p.F1600L | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV56680124; called by muse, mutect2, varscan2
- SPICE1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs1201348007, COSV55625270; called by muse, mutect2, varscan2
- SUSD4 | c.82A>G p.R28G | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV59556852; called by muse, mutect2, varscan2
- TANGO2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs551072560, COSV100529852; called by muse, mutect2, varscan2
- THSD1 | c.837del p.R280Dfs*56 | Frame Shift Del (DEL) | VAF 39/108 reads (36%) | catalogued as rs1566074528; called by mutect2, varscan2
- TMEM260 | c.587A>C p.Y196S | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762594468, COSV55102834; called by muse, varscan2
- TOB1 | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV52150968; called by muse, mutect2, varscan2
- ZFYVE26 | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs866667987, COSV61333702; called by muse, varscan2
- ZIC2 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM091707, COSV66255517; called by muse, mutect2, varscan2
- ZNF273 | c.1247C>G p.T416S | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.06); catalogued as COSV60400939; called by muse, mutect2, varscan2
- ZNF408 | c.983A>C p.Q328P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV61239383; called by muse, mutect2, varscan2
- ZNF644 | c.3161C>A p.S1054* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV61350514; called by muse, mutect2, varscan2
- ACOX2 | c.348_354dup p.H119Kfs*52 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- ATP2B1 | c.3256_3257dup p.L1086Ffs*2 | Frame Shift Ins (INS) | VAF 37/73 reads (51%) | called by mutect2, varscan2
- FOXN1 | c.555del p.Y186Tfs*116 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- YIPF3 | c.349del p.I117Sfs*21 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- BCOR | c.2451T>C p.T817= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as rs751590260, COSV60719100; called by muse, mutect2, varscan2
- BSN | c.2070C>A p.I690= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV56528014; called by muse, mutect2, varscan2
- CLDN9 | c.402C>A p.I134= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as COSV60911729; called by muse, mutect2, varscan2
- CLEC4F | c.1611C>T p.S537= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV55481667; called by muse, mutect2, varscan2
- HDLBP | c.639A>G p.L213= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs200251201, COSV60501095; called by muse, mutect2, varscan2
- KEAP1 | c.144C>A p.G48= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV50648670; called by muse, mutect2, varscan2
- NOD1 | c.627C>T p.S209= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV56112593; called by muse, mutect2, varscan2
- PCDHGA11 | c.39G>A p.L13= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV54037463; called by muse, mutect2, varscan2
- PRKCZ | c.411C>T p.R137= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV66071366; called by muse, mutect2, varscan2
- RMND5A | c.135G>A p.Q45= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV52152655, COSV52155491; called by muse, mutect2, varscan2
- SRRT | c.2175T>C p.P725= | Silent (SNP) | VAF 57/173 reads (33%) | catalogued as COSV53821679; called by muse, mutect2, varscan2
- ULK3 | c.648G>A p.R216= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV51513447; called by muse, mutect2, varscan2
